Somatic mutation profile of tumor specimen TCGA-BR-A4PF-01A (aliquot TCGA-BR-A4PF-01A-11D-A25D-08) from TCGA case TCGA-BR-A4PF, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 72.3 years (26,412 days).
Specimen TCGA-BR-A4PF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a9c15ae-f997-4cb9-b891-e9c3ebf319e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4PF-10A (Blood Derived Normal), aliquot TCGA-BR-A4PF-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5163f42e-ab0b-41ba-bf56-00a6e8f62d9b

The open-access MAF lists 111 somatic variants for this specimen: 93 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 17, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, In Frame Del 2, Splice Site 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD1 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56646955, COSV56647547; called by muse, mutect2, varscan2
- ADCY2 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57869521; called by muse, mutect2, varscan2
- ADRM1 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs370417009; called by mutect2, varscan2
- ANKRD52 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 174/208 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57287212; called by muse, mutect2, varscan2
- BPTF | c.3210_3221del p.N1071_E1074del | In Frame Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs749412697; called by mutect2, varscan2
- C11orf80 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.398); catalogued as COSV100691077; called by muse, mutect2, varscan2
- C19orf47 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs766693508, COSV63510953; called by muse, mutect2, varscan2
- C7orf61 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as COSV55725255; called by muse, mutect2
- CASS4 | c.2133G>A p.M711I | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV64388242; called by muse, mutect2, varscan2
- CDON | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV55001966; called by muse, mutect2, varscan2
- CFHR5 | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV56827525; called by muse, mutect2, varscan2
- CNKSR2 | c.2861G>A p.R954Q | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs762666233, COSV65337821; called by muse, mutect2, varscan2
- CNTLN | c.3032A>G p.E1011G | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV52094935; called by muse, mutect2, varscan2
- CNTN1 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.158); catalogued as COSV61644913; called by muse, mutect2, varscan2
- COL13A1 | c.669C>A p.S223R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV62574481; called by muse, mutect2, varscan2
- CYP2A13 | c.441A>T p.E147D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV57839793, COSV57839816; called by muse, mutect2, varscan2
- DCHS1 | c.5069C>G p.S1690C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1023242194, COSV55035657, COSV55041860; called by muse, mutect2, varscan2
- DPP4 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.451); catalogued as rs1265864737, COSV62108955; called by muse, mutect2, varscan2
- DYNC2H1 | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs747028260, COSV62105224, COSV62112095; called by muse, mutect2, varscan2
- DYSF | c.847T>A p.F283I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.803); catalogued as COSV50554198; called by muse, mutect2, varscan2
- ECI2 | c.812C>T p.P271L (on ENST00000380118 / NM_206836.3; = p.P241L on NM_006117.2) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60987311; called by muse, mutect2, varscan2
- EFS | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1463886157, COSV53732253, COSV53734116; called by muse, mutect2, varscan2
- EXOC1 | c.2429G>A p.R810H | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770669428, COSV62121763; called by muse, mutect2, varscan2
- FAR2 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 73/535 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV51729310; called by muse, mutect2, varscan2
- FAT2 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs147663319; called by muse, mutect2
- FBXO24 | c.767C>A p.T256N (on ENST00000241071 / NM_033506.3; = p.T294N on NM_012172.5) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV53829128; called by muse, mutect2
- FGF3 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61926788; called by muse, mutect2
- FLT3 | c.1802T>C p.L601P | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV54068156; called by muse, mutect2, varscan2
- FUT4 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV62470119; called by muse, mutect2, varscan2
- GLIPR1L1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as COSV56883700; called by muse, mutect2, varscan2
- GNG7 | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV66285975, COSV66287716; called by muse, mutect2, varscan2
- GOLIM4 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.566); catalogued as COSV58331729; called by muse, mutect2, varscan2
- GRID2 | c.1340C>G p.T447S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV56220788, COSV56257737; called by muse, mutect2, varscan2
- GRM3 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs753191583, COSV64478725; called by muse, mutect2, varscan2
- H2BC18 | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.783); catalogued as COSV58944850; called by muse, mutect2, varscan2
- HESX1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766234350, CM1110145, COSV55843341, COSV55843561; called by muse, mutect2, varscan2
- HMCN1 | c.10999C>T p.R3667* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV54895114; called by muse, mutect2, varscan2
- IL19 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV54284621; called by muse, mutect2, varscan2
- IPO5 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV55159201; called by muse, mutect2, varscan2
- KIAA1109 | c.6322A>G p.I2108V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV52689936; called by muse, mutect2, varscan2
- LAMA5 | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs375524294, COSV53358887; called by muse, mutect2, varscan2
- LAMB3 | c.1976G>T p.R659M | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CS983948, COSV61919369; called by muse, mutect2, varscan2
- LRP1B | c.9484G>A p.G3162R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV67268470; called by muse, mutect2, varscan2
- LRRK2 | c.7409T>G p.M2470R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV100110972; called by mutect2, varscan2
- MINDY4 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 53/321 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV54677988; called by muse, mutect2, varscan2
- MKI67 | c.9416G>A p.G3139E | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV64076550; called by muse, mutect2, varscan2
- MUSK | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as rs188464904, COSV51882850; called by muse, mutect2, varscan2
- NKD1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); catalogued as rs751057016, COSV51694037; called by muse, mutect2, varscan2
- NUDCD3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773373200, COSV58126776; called by muse, mutect2, varscan2
- OR2T2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs558609829, COSV100737782; called by muse, mutect2, varscan2
- OR51E1 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV67810870; called by muse, mutect2, varscan2
- OR51G2 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs1288955599, COSV58991743, COSV58993153; called by muse, mutect2, varscan2
- OR52R1 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as rs1423948649, COSV61889312; called by muse, mutect2, varscan2
- OR8J3 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.763); catalogued as rs1415383136, COSV56883906; called by muse, mutect2, varscan2
- PCDH11X | c.187T>G p.F63V | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.98); catalogued as COSV53499780; called by muse, mutect2, varscan2
- PCDHB10 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.049); catalogued as rs2907324, COSV53383227; called by muse, mutect2, varscan2
- PGLYRP2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV52994878; called by muse, mutect2, varscan2
- PIWIL4 | c.1658C>A p.S553Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54412091; called by muse, mutect2, varscan2
- PLEC | c.6377G>A p.R2126H (on ENST00000322810 / NM_201380.4; = p.R2016H on NM_000445.5) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as rs782084501, COSV59689625; called by muse, mutect2, varscan2
- POM121L12 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV68693786, COSV68694233; called by muse, mutect2, varscan2
- PRDM16 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1407647352, COSV54605049, COSV54606419; called by muse, mutect2, varscan2
- PRPF39 | c.1037A>T p.K346I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV63277459; called by muse, mutect2
- PXDNL | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV62478535; called by muse, mutect2, varscan2
- RAB35 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | catalogued as COSV57493843; called by muse, mutect2, varscan2
- RFC1 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs374549255, COSV62899615; called by muse, mutect2, varscan2
- SCN7A | c.741dup p.L248Sfs*19 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | catalogued as rs769551067; called by mutect2, pindel, varscan2
- SHC4 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60116178; called by muse, mutect2, varscan2
- SLC10A5 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV72828472; called by muse, mutect2, varscan2
- SLC43A2 | c.841A>G p.S281G | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56771195; called by muse, mutect2, varscan2
- SMARCA2 | c.1132G>T p.V378L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs753807887, COSV61805594, COSV61809672; called by muse, mutect2, varscan2
- SOGA3 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs770394415, COSV64108410; called by muse, mutect2, varscan2
- STPG2 | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV54817974; called by muse, mutect2
- TDRKH | c.1217+2T>A p.X406_splice | Splice Site (SNP) | VAF 15/86 reads (17%) | catalogued as COSV58619367; called by muse, mutect2, varscan2
- TEX13B | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV57203785; called by muse, mutect2, varscan2
- TMEM255B | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.359); catalogued as rs752630188, COSV64714662; called by muse, mutect2, varscan2
- TNXB | c.7123C>A p.Q2375K (on ENST00000647633; = p.Q2128K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64487971; called by muse, mutect2, varscan2
- TP53 | c.245del p.P82Rfs*41 | Frame Shift Del (DEL) | VAF 73/172 reads (42%) | catalogued as CM961375, COSV53209087; called by mutect2, pindel, varscan2
- TRAF3IP2 | c.243C>G p.H81Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100389854; called by muse, mutect2
- TRIM68 | c.869G>C p.R290P | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV56169941; called by muse, mutect2, varscan2
- TRPM1 | c.1766A>G p.K589R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs777942130, COSV56641186; called by muse, mutect2, varscan2
- TTN | c.3983G>A p.G1328D (on ENST00000591111; = p.G1282D on NM_003319.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | PolyPhen probably damaging (1); catalogued as COSV60304602; called by muse, mutect2, varscan2
- VCAN | c.983T>A p.F328Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.809); catalogued as COSV54115288; called by mutect2, varscan2
- WDFY3 | c.5577_5579del p.E1860del | In Frame Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs1416355010; called by pindel, varscan2
- WSB1 | c.152G>C p.W51S | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52216631; called by muse, mutect2, varscan2
- ZACN | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs140302218, COSV58037935; called by muse, mutect2, varscan2
- ZFAT | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs768580861, COSV64745553; called by muse, mutect2, varscan2
- ZNF584 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 40/102 reads (39%) | catalogued as COSV59723339; called by muse, mutect2, varscan2
- ZNF584 | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV59723343; called by muse, mutect2, varscan2
- MIA3 | c.2394_2395del p.V799Qfs*20 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- PCLO | c.3698dup p.P1234Afs*11 | Frame Shift Ins (INS) | VAF 39/234 reads (17%) | called by mutect2, varscan2
- RABL3 | c.168_173dup p.E57_K58dup | In Frame Ins (INS) | VAF 6/37 reads (16%) | called by mutect2, varscan2
- RBP3 | c.2960C>A p.A987D | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- RNF122 | c.133_146del p.G45Hfs*21 | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | called by mutect2, pindel, varscan2
- C10orf71 | c.258G>A p.P86= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as rs192160684, COSV60512202; called by muse, mutect2, varscan2
- CCDC102B | c.246G>A p.K82= | Silent (SNP) | VAF 29/234 reads (12%) | catalogued as COSV60152813; called by muse, mutect2, varscan2
- DNAJB6 | c.150G>A p.A50= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs141947451, COSV51099670; called by mutect2, varscan2
- FLG | c.10545C>T p.S3515= | Silent (SNP) | VAF 71/410 reads (17%) | catalogued as COSV64247813; called by muse, mutect2, varscan2
- IGHG4 | c.732C>T p.S244= | Silent (SNP) | VAF 65/420 reads (15%) | called by muse, mutect2, varscan2
- IHH | c.123A>G p.P41= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV55393943; called by muse, mutect2, varscan2
- IQGAP3 | c.3258T>C p.T1086= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100752310; called by muse, mutect2, varscan2
- KCNT2 | c.1959T>C p.D653= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV54105514; called by muse, mutect2, varscan2
- KIF3B | c.81G>A p.S27= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs755906082, COSV65227578; called by muse, mutect2, varscan2
- NETO1 | c.1485C>T p.I495= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs201303366, COSV100198322, COSV55003064; called by mutect2, varscan2
- OR51D1 | c.600G>T p.L200= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV62914780; called by muse, mutect2, varscan2
- SEMA6D | c.867T>C p.D289= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV60383094; called by muse, mutect2, varscan2
- SPATA5 | c.1674A>G p.G558= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV56783258; called by muse, mutect2, varscan2
- STAM2 | c.792T>G p.T264= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV55733886; called by muse, mutect2
- SYNE1 | c.14967T>G p.T4989= (on ENST00000367255 / NM_182961.4; = p.T4918= on NM_033071.3) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV55085272; called by muse, mutect2
- YOD1 | c.468A>C p.A156= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100263213; called by muse, mutect2, varscan2
- ZNF282 | c.273G>A p.L91= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV50482966; called by muse, mutect2, varscan2
- DDX39B | c.616+107A>G | Intron (SNP) | VAF 16/48 reads (33%) | catalogued as rs913763708, COSV100795189, COSV100795275; called by muse, varscan2
